Somatic mutation profile of tumor specimen C3N-03890-01 (aliquot CPT0221310006) from CPTAC case C3N-03890, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 63.2 years (23,096 days).
Specimen C3N-03890-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 771e7ef1-4c93-4d40-be2e-237e19842e80.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03890-71 (Blood Derived Normal), aliquot CPT0221560002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2c4e50d4-674e-4a00-8405-a687c6b2afdc

The open-access MAF lists 65 somatic variants for this specimen: 42 protein-altering or splice-affecting, 18 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, Silent 18, Intron 3, Splice Region 2, 5'Flank 2, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 119/593 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- MLH1 | c.116+3A>G | Splice Region (SNP) | VAF 32/305 reads (10%) | catalogued as rs1553637475; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AURKC | c.434C>T p.T145M (on ENST00000302804 / NM_001015878.2; = p.T111M on NM_003160.3) | Missense Mutation (SNP) | VAF 58/397 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.403); catalogued as rs45503793, COSV57138405; called by muse, mutect2, varscan2
- CASK | c.2620C>T p.R874C (on ENST00000378163 / NM_001367721.1; = p.R869C on NM_003688.3) | Missense Mutation (SNP) | VAF 16/209 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1204576497, COSV59364263; called by muse, mutect2
- CR1 | c.2539G>T p.A847S | Missense Mutation (SNP) | VAF 50/465 reads (11%) | SIFT tolerated (0.58); PolyPhen benign (0.399); catalogued as rs1174374251; called by muse, mutect2, varscan2
- DEFB118 | c.190C>T p.R64* | Nonsense Mutation (SNP) | VAF 69/424 reads (16%) | catalogued as rs1378169108, COSV53621156; called by muse, mutect2, varscan2
- EDN3 | c.554C>T p.T185M | Missense Mutation (SNP) | VAF 41/396 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.749); catalogued as rs368327225, CM1310571; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FLG | c.8713G>A p.E2905K | Missense Mutation (SNP) | VAF 39/1010 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.045); catalogued as COSV64243100, COSV64244907; called by muse, mutect2
- KCNQ2 | c.2399G>A p.R800H (on ENST00000359125 / NM_172107.4; = p.R772H on NM_004518.6) | Missense Mutation (SNP) | VAF 30/484 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.115); catalogued as rs772301648, COSV104416079; called by muse, mutect2
- MAGEA8 | c.791C>T p.A264V | Missense Mutation (SNP) | VAF 17/194 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1557371039, COSV54064054; called by muse, mutect2
- MED24 | c.985-1G>C p.X329_splice | Splice Site (SNP) | VAF 8/77 reads (10%) | catalogued as COSV100673129; called by muse, mutect2, varscan2
- NACA2 | c.88G>C p.D30H | Missense Mutation (SNP) | VAF 20/396 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.735); catalogued as COSV71713062; called by muse, mutect2
- NFE2L3 | c.1103T>C p.V368A | Missense Mutation (SNP) | VAF 20/362 reads (6%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as rs778082166; called by muse, mutect2
- OPN5 | c.928G>C p.D310H | Missense Mutation (SNP) | VAF 13/284 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.547); catalogued as COSV99789650; called by muse, mutect2
- POLA1 | c.4202C>T p.A1401V | Missense Mutation (SNP) | VAF 11/330 reads (3%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as rs1453680052; called by muse, mutect2
- PPP1R2C | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 15/317 reads (5%) | SIFT tolerated (0.49); PolyPhen benign (0.017); catalogued as COSV100973221; called by muse, mutect2
- TCIRG1 | c.1421C>G p.S474W | Missense Mutation (SNP) | VAF 16/204 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199914625, CM042494, COSV55835226; called by muse, mutect2
- TRIO | c.8896G>A p.G2966R | Missense Mutation (SNP) | VAF 18/278 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201455780, COSV59990553; called by muse, mutect2
- ZNF536 | c.1037G>A p.R346H | Missense Mutation (SNP) | VAF 25/326 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as rs139757559; called by muse, mutect2
- AAK1 | c.1179G>T p.R393S | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- AMOT | c.199C>T p.H67Y | Missense Mutation (SNP) | VAF 7/157 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.25); called by muse, mutect2
- C17orf64 | c.701C>A p.T234N | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); called by mutect2, varscan2
- CAMK1G | c.401T>G p.L134R | Missense Mutation (SNP) | VAF 10/176 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CCT6A | c.649C>T p.R217W | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.226); called by muse, mutect2, varscan2
- CEP295 | c.1702A>G p.I568V | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0.007); called by muse, mutect2
- CSMD3 | c.7396A>T p.T2466S (on ENST00000297405 / NM_001363185.1; = p.T2362S on NM_052900.3) | Missense Mutation (SNP) | VAF 48/404 reads (12%) | SIFT tolerated (0.78); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- DLK2 | c.362C>T p.P121L | Missense Mutation (SNP) | VAF 20/316 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2
- DNAH2 | c.12535G>T p.A4179S | Missense Mutation (SNP) | VAF 31/401 reads (8%) | SIFT tolerated (0.45); PolyPhen benign (0.05); called by muse, mutect2
- FAM114A1 | c.1415G>A p.G472E | Missense Mutation (SNP) | VAF 9/184 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GABRE | c.418C>T p.L140F | Missense Mutation (SNP) | VAF 18/216 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.027); called by muse, mutect2
- KIF26B | c.1360A>T p.M454L | Missense Mutation (SNP) | VAF 18/234 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.73); called by muse, mutect2
- MID1 | c.652A>G p.K218E | Missense Mutation (SNP) | VAF 14/291 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.119); called by muse, mutect2
- MSN | c.1706A>G p.Q569R | Missense Mutation (SNP) | VAF 9/113 reads (8%) | SIFT tolerated (0.36); PolyPhen benign (0.072); called by muse, mutect2
- PARP12 | c.962C>G p.A321G | Missense Mutation (SNP) | VAF 13/160 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.424); called by muse, mutect2
- PCDHGB4 | c.646G>T p.D216Y | Missense Mutation (SNP) | VAF 9/110 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PLS3 | c.1618T>G p.S540A | Missense Mutation (SNP) | VAF 16/159 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SAMD9 | c.3865G>A p.E1289K | Missense Mutation (SNP) | VAF 27/418 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.3); called by muse, mutect2
- SETD1B | c.5585G>A p.R1862H | Missense Mutation (SNP) | VAF 15/179 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- TMED7 | c.430C>G p.L144V | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2
- TSC22D1 | c.2964+7A>G | Splice Region (SNP) | VAF 14/123 reads (11%) | called by muse, mutect2, varscan2
- ZNF85 | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 14/472 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- ZP1 | c.418C>G p.P140A | Missense Mutation (SNP) | VAF 20/175 reads (11%) | SIFT tolerated (0.67); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ATP2B3 | c.2136C>A p.A712= | Silent (SNP) | VAF 22/290 reads (8%) | called by muse, mutect2
- CAMK1G | c.402A>C p.L134= | Silent (SNP) | VAF 10/174 reads (6%) | called by muse, mutect2
- CDH11 | c.2199G>A p.T733= | Silent (SNP) | VAF 18/373 reads (5%) | catalogued as rs776762339, COSV51750484; called by muse, mutect2
- CNTRL | c.3960C>T p.N1320= | Silent (SNP) | VAF 14/137 reads (10%) | catalogued as rs1309814141; called by muse, mutect2, varscan2
- ERBB4 | c.1333C>T p.L445= | Silent (SNP) | VAF 23/279 reads (8%) | catalogued as rs767472865, COSV53581973; called by muse, mutect2
- EYS | c.8466G>C p.G2822= (on ENST00000370621 / NM_001292009.1; = p.G2801= on NM_001142800.2) | Silent (SNP) | VAF 22/302 reads (7%) | called by muse, mutect2
- F5 | c.417C>T p.D139= | Silent (SNP) | VAF 45/412 reads (11%) | catalogued as rs749722664, COSV63120009; ClinVar: likely benign; called by muse, mutect2, varscan2
- GAB4 | c.651G>A p.S217= | Silent (SNP) | VAF 13/103 reads (13%) | catalogued as rs757635484, COSV68753868; called by muse, mutect2, varscan2
- GPRC6A | c.417A>G p.R139= | Silent (SNP) | VAF 21/207 reads (10%) | catalogued as COSV59952671; called by muse, mutect2, varscan2
- H1-4 | c.522A>G p.K174= | Silent (SNP) | VAF 32/406 reads (8%) | called by muse, mutect2
- MAF1 | c.99A>G p.S33= | Silent (SNP) | VAF 31/280 reads (11%) | catalogued as rs753452002; called by muse, mutect2, varscan2
- MED12 | c.2916T>G p.L972= | Silent (SNP) | VAF 26/362 reads (7%) | called by muse, mutect2
- NCAM2 | c.408C>T p.C136= | Silent (SNP) | VAF 11/147 reads (7%) | catalogued as COSV53079959; called by muse, mutect2
- RBM12B | c.925C>T p.L309= | Silent (SNP) | VAF 8/130 reads (6%) | called by muse, mutect2
- SERAC1 | c.501G>A p.R167= | Silent (SNP) | VAF 8/83 reads (10%) | called by muse, mutect2
- SSTR4 | c.423C>T p.S141= | Silent (SNP) | VAF 13/113 reads (12%) | catalogued as rs778910626; called by muse, mutect2, varscan2
- TP53TG5 | c.705C>G p.V235= | Silent (SNP) | VAF 34/263 reads (13%) | called by muse, mutect2, varscan2
- ZCCHC14 | c.2511C>T p.S837= (on ENST00000268616; = p.S974= on NM_015144.3) | Silent (SNP) | VAF 20/288 reads (7%) | catalogued as rs778091645; called by muse, mutect2
- AC244517.10 | c.36-8959C>T | Intron (SNP) | VAF 30/642 reads (5%) | called by muse, mutect2
- DCAF13 | chr8:103415344 T>G | 5'Flank (SNP) | VAF 15/308 reads (5%) | catalogued as COSV52567093, COSV52567749, COSV52568626; called by muse, mutect2
- DDHD1 | chr14:53152520 G>A | 5'Flank (SNP) | VAF 24/340 reads (7%) | catalogued as rs149564453; ClinVar: likely benign; called by muse, mutect2
- MLH3 | c.4091-25C>T | Intron (SNP) | VAF 14/154 reads (9%) | called by muse, mutect2
- PPP2R3B | c.325-12098C>T | Intron (SNP) | VAF 3/37 reads (8%) | catalogued as rs1478966631; called by muse, mutect2
